Somatic mutation profile of tumor specimen TCGA-CG-4437-01A (aliquot TCGA-CG-4437-01A-01D-1800-08) from TCGA case TCGA-CG-4437, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 83.4 years (30,467 days).
Specimen TCGA-CG-4437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9deb8810-1a6b-45ab-9747-896d5f4b07fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4437-10A (Blood Derived Normal), aliquot TCGA-CG-4437-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5939edb-cc16-4cc0-a9e6-f02d6c326c7e

The open-access MAF lists 576 somatic variants for this specimen: 440 protein-altering or splice-affecting, 121 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 371, Silent 121, Frame Shift Del 27, Nonsense Mutation 13, In Frame Del 11, Splice Site 10, Intron 7, Splice Region 6, RNA 5, 3'UTR 2, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.5468+1G>T p.X1823_splice (on ENST00000272895 / NM_173076.3; = p.X1505_splice on NM_015657.3) | Splice Site (SNP) | VAF 34/157 reads (22%) | catalogued as COSV55959418; called by muse, mutect2, varscan2
- ABCA13 | c.8812G>A p.V2938I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1334409232, COSV71286457; called by muse, mutect2
- ABCA13 | c.12704T>A p.L4235H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV68946786; called by muse, mutect2
- ABCA13 | c.13922G>T p.G4641V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68946790; called by mutect2, varscan2
- ABCB4 | c.165G>T p.L55F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV55935407, COSV55943047; called by muse, mutect2, varscan2
- ABHD15 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as rs1463110551, COSV56195333; called by muse, mutect2, varscan2
- ACTG2 | c.681G>C p.E227D | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); catalogued as COSV61828343; called by muse, mutect2, varscan2
- ACTR3B | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV55449081; called by muse, mutect2, varscan2
- ADAM2 | c.1715G>A p.C572Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55862129; called by muse, mutect2, varscan2
- ADAMTS10 | c.939C>G p.S313R | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54354871; called by muse, mutect2, varscan2
- ADAMTS16 | c.2227T>C p.S743P | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56982957, COSV57000682, COSV99943085; called by muse, mutect2, varscan2
- ADAMTS2 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV51078436; called by muse, mutect2, varscan2
- ADSS2 | c.827T>A p.V276D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63695113; called by muse, mutect2, varscan2
- AGBL2 | c.1082A>G p.K361R | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54092003; called by muse, mutect2, varscan2
- AMPD3 | c.1246T>G p.Y416D (on ENST00000396553 / NM_001025389.2; = p.Y425D on NM_000480.3) | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67330938; called by muse, varscan2
- ANK2 | c.5307A>T p.K1769N | Missense Mutation (SNP) | VAF 113/369 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52161221; called by muse, mutect2, varscan2
- APH1B | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV56013696, COSV56014386; called by muse, mutect2, varscan2
- APOB | c.11407C>T p.P3803S | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.044); catalogued as COSV51935269; called by muse, mutect2, varscan2
- APOL5 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV50766918; called by muse, mutect2, varscan2
- APP | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV60998605; called by muse, mutect2, varscan2
- ARFGEF3 | c.1259T>G p.I420S | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.368); catalogued as COSV52457431; called by muse, mutect2, varscan2
- ARL3 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV53299674; called by muse, mutect2, varscan2
- ASAP3 | c.1274C>G p.T425R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV60874681; called by muse, mutect2, varscan2
- ASB4 | c.986A>G p.Q329R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV57945290; called by muse, mutect2
- ASPM | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as COSV99659264; called by muse, mutect2, varscan2
- ATAD5 | c.219T>G p.N73K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV58974654; called by muse, mutect2, varscan2
- ATP10B | c.1224G>C p.E408D | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.434); catalogued as COSV58778802; called by muse, mutect2, varscan2
- ATP12A | c.2347A>G p.I783V | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV54516171; called by muse, mutect2, varscan2
- ATP13A5 | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.097); catalogued as COSV60869314; called by muse, mutect2, varscan2
- ATP2B3 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1026134252; called by muse, mutect2
- ATP6V0A1 | c.1022C>A p.T341K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV52873474; called by muse, mutect2
- ATP6V0A4 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as COSV59475698; called by muse, mutect2
- BEND7 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1245642029, COSV61988982; called by muse, mutect2, varscan2
- BRPF3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.026); catalogued as rs543987259, COSV60207418; called by muse, mutect2, varscan2
- C4orf33 | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.834); catalogued as COSV55415943; called by muse, mutect2, varscan2
- C8orf58 | c.133T>A p.S45T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.584); catalogued as COSV51515214; called by muse, mutect2, varscan2
- C8orf76 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52690567; called by muse, mutect2, varscan2
- CACNA1A | c.3131C>T p.S1044L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs776628272, COSV64198060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV53126025; called by muse, mutect2, varscan2
- CADPS | c.461A>C p.Q154P | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV51879979; called by muse, mutect2, varscan2
- CALCR | c.128T>G p.V43G | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV64008181; called by muse, mutect2, varscan2
- CAPRIN1 | c.1432A>C p.T478P | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV58219835; called by muse, mutect2, varscan2
- CARMIL2 | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58026305; called by muse, mutect2, varscan2
- CASKIN1 | c.1734G>A p.W578* | Nonsense Mutation (SNP) | VAF 48/120 reads (40%) | catalogued as COSV58214418; called by muse, mutect2, varscan2
- CCDC142 | c.1874C>T p.S625F (on ENST00000393965 / NM_001365575.2; = p.S618F on NM_032779.4) | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV50688544; called by muse, mutect2, varscan2
- CCDC80 | c.1922A>G p.Q641R | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1172845552, COSV52816827; called by muse, mutect2, varscan2
- CCDC88A | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1402662593, COSV55061623; called by muse, mutect2, varscan2
- CDH23 | c.5667C>A p.N1889K | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); catalogued as COSV56463596; called by muse, mutect2, varscan2
- CDH9 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs568693690, COSV50256740, COSV50269687; called by muse, mutect2, varscan2
- CELA2A | c.715T>G p.S239A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62747498; called by muse, mutect2, varscan2
- CEMIP | c.3781C>T p.H1261Y | Missense Mutation (SNP) | VAF 52/476 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs768391358, COSV54992651; called by muse, mutect2, varscan2
- CGNL1 | c.2404-1G>C p.X802_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV55567753; called by muse, mutect2
- CGNL1 | c.2827C>T p.R943W | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778467834, COSV55567766; called by muse, mutect2, varscan2
- CHD6 | c.6640G>A p.E2214K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV64690781; called by muse, mutect2, varscan2
- CHD9 | c.911A>C p.D304A | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.196); catalogued as COSV68298186; called by muse, mutect2, varscan2
- CHPF2 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV50390888; called by muse, mutect2, varscan2
- CIT | c.5896C>G p.L1966V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV55868698; called by muse, mutect2, varscan2
- CLEC6A | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV65987144; called by muse, mutect2, varscan2
- CLN3 | c.1190C>G p.S397C (on ENST00000360019 / NM_001286104.2; = p.S421C on NM_000086.2) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61105841, COSV61108108; called by muse, mutect2, varscan2
- CLU | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV57066739; called by muse, mutect2
- CNBP | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV69654591; called by muse, mutect2
- CNGA3 | c.1048A>G p.R350G | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV55624317; called by muse, mutect2, varscan2
- CNIH3 | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55275747; called by muse, mutect2, varscan2
- CNMD | c.431T>G p.V144G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV65033018; called by muse, mutect2, varscan2
- CNOT10 | c.1786C>G p.P596A | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59392120; called by muse, mutect2, varscan2
- CNTN4 | c.686T>A p.V229E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61873067; called by muse, mutect2
- CNTNAP1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); catalogued as rs763919892, COSV52848858, COSV52849023; called by muse, mutect2, varscan2
- COL14A1 | c.3702A>C p.E1234D | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV52854387; called by muse, mutect2, varscan2
- COL19A1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV59573346; called by muse, mutect2, varscan2
- COL28A1 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV68082126; called by muse, mutect2, varscan2
- COL4A1 | c.4238C>A p.A1413D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as COSV65425684; called by muse, mutect2, varscan2
- COPZ1 | c.476C>A p.T159N | Missense Mutation (SNP) | VAF 119/452 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV50432344; called by muse, mutect2, varscan2
- CPO | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55939841; called by muse, mutect2, varscan2
- CR1L | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.174); catalogued as COSV54326306; called by muse, mutect2, varscan2
- CREBRF | c.113A>G p.D38G | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51633101; called by muse, mutect2, varscan2
- CRYZL1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51677532; called by muse, mutect2, varscan2
- CSAD | c.34G>A p.G12R (on ENST00000444623 / NM_001244705.2; = p.G39R on NM_015989.5) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV57242703; called by muse, mutect2, varscan2
- CSF3R | c.2434G>T p.V812F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV58966737; called by muse, varscan2
- CSF3R | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV100117137; called by muse, mutect2
- CSMD2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs761180145, COSV53892340; called by muse, mutect2, varscan2
- CSMD3 | c.6290T>A p.V2097E (on ENST00000297405 / NM_001363185.1; = p.V1993E on NM_052900.3) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV52181237, COSV99844343; called by muse, mutect2
- CTH | c.1169T>C p.L390P | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61008480; called by muse, mutect2, varscan2
- CTTNBP2NL | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54744410, COSV54744469; called by muse, mutect2, varscan2
- CYBRD1 | c.298T>A p.S100T | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV58426617; called by muse, mutect2, varscan2
- CYP4F8 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57854024; called by muse, mutect2, varscan2
- DBN1 | c.516G>C p.M172I | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.472); catalogued as COSV52789645; called by muse, mutect2, varscan2
- DCAF4 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs761101704, COSV62319576; called by muse, mutect2, varscan2
- DCDC2 | c.748T>C p.S250P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); catalogued as COSV65831928; called by muse, mutect2
- DCST2 | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV55051818; called by muse, mutect2
- DESI2 | c.89A>C p.H30P | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55641352; called by muse, mutect2, varscan2
- DGCR2 | c.1195T>A p.F399I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54218521; called by muse, mutect2, varscan2
- DHTKD1 | c.1307A>T p.N436I | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53803614; called by muse, mutect2
- DHX40 | c.2240G>C p.R747T | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV52067549; called by muse, mutect2, varscan2
- DHX8 | c.1923G>A p.E641= | Splice Region (SNP) | VAF 40/118 reads (34%) | catalogued as COSV52253378; called by muse, mutect2, varscan2
- DISP2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV51121864; called by muse, mutect2, varscan2
- DNAH10 | c.7033T>C p.Y2345H (on ENST00000409039; = p.Y2284H on NM_207437.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68993805; called by muse, mutect2, varscan2
- DNAH11 | c.7726G>A p.D2576N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1282090941, COSV60957558; called by muse, mutect2
- DNAH17 | c.1667T>G p.L556R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67754376; called by muse, varscan2
- DNAH2 | c.8827G>T p.E2943* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV66719469; called by muse, mutect2
- DNAJB5 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV56624917, COSV56625584; called by muse, mutect2, varscan2
- DNMT3L | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 34/95 reads (36%) | catalogued as rs368058982, COSV99533324; called by muse, mutect2, varscan2
- DPP4 | c.1459A>C p.N487H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV62106745; called by muse, mutect2
- EBAG9 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100520715; called by muse, mutect2
- EFCAB6 | c.4470C>G p.I1490M | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs764511716, COSV53063262; called by muse, mutect2, varscan2
- EGF | c.1953C>A p.F651L | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV54478804; called by muse, mutect2, varscan2
- ELL2 | c.547T>G p.S183A | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.253); catalogued as COSV52982512; called by muse, mutect2, varscan2
- EPB41L3 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100550650, COSV59453589; called by muse, mutect2, varscan2
- EPHA10 | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57624021; called by muse, mutect2
- ERICH1 | c.1157T>A p.V386E | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50638248; called by muse, mutect2
- ERN1 | c.2424G>C p.L808F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70502235; called by muse, mutect2, varscan2
- ESR2 | c.1576A>T p.N526Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV50831078; called by muse, mutect2, varscan2
- FAM160B2 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV57158533; called by muse, mutect2, varscan2
- FAM189A2 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.08); catalogued as COSV57384700; called by muse, mutect2, varscan2
- FAT2 | c.3227G>T p.G1076V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs772579836, COSV55819716; called by muse, mutect2, varscan2
- FGF1 | c.331A>C p.T111P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61803739; called by muse, mutect2, varscan2
- FHOD3 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV57173419; called by muse, mutect2, varscan2
- FLNA | c.6752C>T p.A2251V (on ENST00000369850 / NM_001110556.2; = p.A2243V on NM_001456.3) | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV61043007; called by muse, mutect2, varscan2
- FOXP4 | c.1391C>A p.A464D (on ENST00000307972 / NM_001012426.1; = p.A451D on NM_138457.3) | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV57220047; called by muse, mutect2, varscan2
- FRMPD3 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs769308576, COSV52186679; called by muse, mutect2, varscan2
- FSHR | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58623662; called by muse, mutect2
- FTSJ3 | c.2267G>C p.R756T | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV63790118; called by muse, mutect2, varscan2
- FUT4 | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV62469321; called by muse, mutect2
- FZR1 | c.171G>C p.W57C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV58051803; called by muse, mutect2, varscan2
- GAB3 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65819574; called by muse, mutect2, varscan2
- GAB4 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV68753842; called by muse, mutect2, varscan2
- GABRR3 | c.1021G>C p.V341L | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1299528908, COSV72084101; called by muse, mutect2, varscan2
- GALNT18 | c.787C>G p.P263A | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57146071, COSV57149321; called by muse, mutect2, varscan2
- GALNT2 | c.728A>C p.E243A | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64194856; called by muse, mutect2
- GALNT9 | c.1685G>C p.R562P (on ENST00000328957 / NM_001122636.2; = p.R196P on NM_021808.3) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61098709; called by muse, mutect2, varscan2
- GARRE1 | c.2830C>G p.H944D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55099261; called by muse, mutect2, varscan2
- GJA1 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as CM030466, COSV56998026; called by muse, mutect2, varscan2
- GJA5 | c.29T>G p.F10C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54784167; called by muse, mutect2, varscan2
- GLDN | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59090104; called by muse, mutect2, varscan2
- GLYR1 | c.1274T>C p.F425S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58927110; called by muse, mutect2, varscan2
- GPC4 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 128/237 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63697530, COSV63697850; called by muse, mutect2, varscan2
- GPNMB | c.1237G>C p.V413L (on ENST00000381990 / NM_001005340.2; = p.V401L on NM_002510.3) | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV51698434; called by muse, mutect2, varscan2
- GPX6 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs370778325, COSV62657550; called by muse, mutect2, varscan2
- GRB7 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV58447953; called by muse, mutect2, varscan2
- GRID2 | c.2491T>A p.F831I | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56205843; called by muse, mutect2, varscan2
- GRIK1 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1053395983, COSV58718191; called by muse, mutect2, varscan2
- GSTA5 | c.644A>T p.E215V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52862171; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2246G>T p.G749V (on ENST00000265755 / NM_016328.3; = p.G734V on NM_005685.4) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56086692; called by muse, mutect2, varscan2
- GTF3C5 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV59599957; called by mutect2, varscan2
- GYS1 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54402851; called by muse, mutect2, varscan2
- HDX | c.2017G>T p.D673Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52974660, COSV52976742; called by muse, mutect2, varscan2
- HECTD4 | c.10816T>A p.F3606I | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.958); catalogued as COSV66392026; called by muse, mutect2, varscan2
- HERPUD2 | c.1013T>G p.V338G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100257968, COSV60945037; called by muse, mutect2, varscan2
- HGD | c.601T>G p.L201V | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV52198118; called by muse, mutect2, varscan2
- HIVEP1 | c.5608A>C p.T1870P | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs1421860812, COSV65101422; called by muse, mutect2, varscan2
- HMCN1 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); catalogued as COSV54900598; called by muse, mutect2
- HMCN1 | c.9363+2T>A p.X3121_splice | Splice Site (SNP) | VAF 10/153 reads (7%) | catalogued as COSV54900608; called by muse, mutect2
- HRH1 | c.1217A>T p.H406L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV67955440; called by muse, mutect2, varscan2
- HTRA2 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51207588; called by muse, mutect2, varscan2
- ICE1 | c.2769C>G p.S923R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1373799513, COSV56824976; called by muse, mutect2, varscan2
- IDH3B | c.584A>C p.Q195P | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV61389986; called by muse, mutect2, varscan2
- IFT140 | c.1009+1G>T p.X337_splice | Splice Site (SNP) | VAF 19/93 reads (20%) | catalogued as rs1221367358, COSV68488603; called by muse, mutect2, varscan2
- IGF2BP3 | c.905T>A p.I302N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV51684647; called by muse, mutect2, varscan2
- IGFL2 | c.241C>A p.L81I (on ENST00000377693 / NM_001135113.2; = p.L92I on NM_001002915.2) | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.09); catalogued as COSV66616709, COSV66616884; called by muse, mutect2, varscan2
- IGFL4 | c.323G>C p.C108S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66618862; called by muse, mutect2
- IKBKE | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65625487; called by muse, mutect2, varscan2
- IMMP2L | c.195A>T p.K65N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.188); catalogued as rs200098844, COSV59237891; called by muse, mutect2, varscan2
- INTU | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as rs1385412062, COSV58871658; called by muse, mutect2, varscan2
- IQCH | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.309); catalogued as COSV60052795; called by muse, mutect2, varscan2
- ITGA10 | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65197399; called by muse, mutect2, varscan2
- JAK3 | c.968C>G p.T323R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV71686051; called by muse, mutect2
- KALRN | c.3873G>C p.Q1291H | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53764077; called by muse, mutect2, varscan2
- KCNH3 | c.2177C>A p.S726Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as rs1327727740, COSV57790801; called by muse, mutect2, varscan2
- KCNH4 | c.1590G>A p.E530= | Splice Region (SNP) | VAF 18/76 reads (24%) | catalogued as COSV52917502; called by muse, mutect2, varscan2
- KCNIP3 | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1446736217, COSV54668720; called by muse, mutect2, varscan2
- KCTD17 | c.917C>G p.P306R (on ENST00000403888 / NM_001282684.1; = p.P282R on NM_024681.3) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV60978173; called by muse, mutect2, varscan2
- KIAA1586 | c.563T>C p.L188S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.094); catalogued as rs1386353906, COSV66056622; called by muse, mutect2, varscan2
- KIF11 | c.2442G>C p.E814D | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53270694; called by muse, mutect2, varscan2
- KIF14 | c.2905C>A p.L969I | Missense Mutation (SNP) | VAF 100/231 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV66261743; called by muse, mutect2, varscan2
- KIF1B | c.380T>G p.F127C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55808744; called by muse, mutect2, varscan2
- KIZ | c.1923T>A p.N641K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55685018; called by muse, mutect2, varscan2
- KLHL41 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52930156, COSV52930239; called by muse, mutect2, varscan2
- KMT2E | c.4810G>C p.V1604L | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as COSV57573341; called by muse, mutect2, varscan2
- KRIT1 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370360812, CM150780; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KRT12 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs1305542803, COSV52430801; called by muse, mutect2, varscan2
- KRT27 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV56971830; called by muse, mutect2, varscan2
- KRT36 | c.766G>C p.V256L | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV60203391; called by muse, mutect2, varscan2
- KRT37 | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56658072; called by muse, mutect2, varscan2
- KRT38 | c.274T>C p.C92R | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55846031; called by muse, mutect2, varscan2
- KRT4 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53407271; called by muse, mutect2, varscan2
- KRT81 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs34187924; called by muse, mutect2, varscan2
- KRTAP26-1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as rs146155445, COSV62128788; called by muse, mutect2, varscan2
- KSR2 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56672547; called by muse, mutect2, varscan2
- LAMA2 | c.202A>T p.K68* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV70347238; called by muse, mutect2, varscan2
- LAMA2 | c.819A>T p.R273S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70347241; called by muse, mutect2, varscan2
- LEPR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267598694, COSV62747060; called by muse, mutect2, varscan2
- LGI3 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs143158388; called by muse, mutect2, varscan2
- LGSN | c.1476G>C p.L492F | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV65727221; called by muse, mutect2, varscan2
- LHFPL3 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67811438; called by muse, mutect2, varscan2
- LIG3 | c.2349G>T p.E783D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52007672; called by muse, mutect2, varscan2
- LNP1 | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs772104310, COSV67346691; called by muse, mutect2
- LRRC37A3 | c.110C>G p.A37G | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs754037903, COSV100140751, COSV59764567; called by muse, mutect2
- LRRN4 | c.1717C>T p.L573F | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs760454962, COSV66645306; called by muse, mutect2, varscan2
- MAGEB6 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs775309752, COSV66872276, COSV66872702; called by muse, mutect2, varscan2
- MAGED1 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.935); catalogued as COSV58515264; called by muse, mutect2, varscan2
- MAMDC4 | c.3143C>T p.P1048L (on ENST00000445819; = p.P969L on NM_206920.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV56375843; called by muse, mutect2, varscan2
- MAMLD1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV53374887; called by muse, mutect2, varscan2
- MAP2K6 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV63006005; called by muse, mutect2, varscan2
- MARCO | c.710T>A p.I237N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV59054391; called by muse, mutect2, varscan2
- MED23 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.255); catalogued as rs752075407, COSV63432504; called by muse, mutect2, varscan2
- MED6 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369104553; called by mutect2, varscan2
- MELTF | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369994330, COSV56381236; called by muse, mutect2, varscan2
- MMRN1 | c.961A>T p.M321L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs201813411, COSV53337443; called by muse, mutect2, varscan2
- MSL2 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53863836; called by muse, mutect2, varscan2
- MTMR4 | c.1698G>A p.W566* | Nonsense Mutation (SNP) | VAF 33/392 reads (8%) | catalogued as COSV60200636; called by muse, mutect2
- MYH2 | c.2609C>A p.A870D | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.279); catalogued as COSV55438263; called by muse, mutect2, varscan2
- MYH4 | c.3406G>T p.A1136S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as COSV55118170; called by muse, mutect2, varscan2
- MYO7B | c.2232A>T p.K744N | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67347705; called by muse, mutect2, varscan2
- NCOR1 | c.1447A>T p.K483* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV51972290, COSV99246362; called by muse, mutect2, varscan2
- NCOR1 | c.1446G>T p.K482N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51962669, COSV99246370; called by muse, mutect2, varscan2
- NDUFC2 | c.224T>G p.V75G | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.39); catalogued as COSV55246334; called by muse, mutect2, varscan2
- NFASC | c.1412G>A p.S471N (on ENST00000339876 / NM_001378329.1; = p.S482N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV58365493; called by muse, mutect2, varscan2
- NFATC4 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51602473; called by muse, mutect2, varscan2
- NHP2 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51070980; called by muse, mutect2, varscan2
- NMB | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV64685511; called by muse, varscan2
- NOTCH2 | c.2044G>C p.D682H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56691447; called by muse, mutect2, varscan2
- NPAT | c.918C>A p.H306Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53718066; called by muse, mutect2, varscan2
- NPBWR2 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs370207328; called by muse, mutect2, varscan2
- NPHP4 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1453723348, COSV65394906; called by muse, mutect2, varscan2
- NRP1 | c.2014A>G p.K672E | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV55167024; called by muse, mutect2, varscan2
- NUFIP1 | c.1005G>C p.L335F | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV64791193; called by muse, mutect2
- NUMA1 | c.4280G>A p.R1427Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as rs913108787, COSV61185607; called by muse, mutect2, varscan2
- NUMA1 | c.1183T>C p.S395P | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV61185613; called by muse, mutect2, varscan2
- NYAP2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as rs761168029, COSV56001990; called by mutect2, varscan2
- OGN | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52760907; called by muse, mutect2, varscan2
- OLFML2A | c.1673T>C p.L558P | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56583388; called by muse, mutect2, varscan2
- OR10Z1 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV63523871, COSV63524054; called by muse, mutect2, varscan2
- OR14A16 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs147527565; called by muse, mutect2, varscan2
- OR1Q1 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs138056123; called by muse, mutect2, varscan2
- OR4A15 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV59033700, COSV59033816; called by muse, mutect2, varscan2
- OR5B3 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as COSV58677191; called by muse, mutect2, varscan2
- OR8H1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs142532321, CM125354, COSV57292940, COSV57293327; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1834G>T p.A612S (on ENST00000259318 / NM_001136562.3; = p.A843S on NM_007203.5) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV52176307; called by muse, mutect2, varscan2
- PCDHA11 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV56501502, COSV56551821; called by muse, mutect2, varscan2
- PCDHA8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV65325085; called by muse, mutect2, varscan2
- PCDHB1 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs116101801, COSV60630920, COSV60633681; called by muse, mutect2, varscan2
- PCDHB11 | c.2300T>C p.L767P | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV61311590; called by muse, mutect2, varscan2
- PCDHB3 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs782303541, COSV50573549; called by muse, mutect2, varscan2
- PCDHGB1 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs775400971, COSV53947801; called by muse, mutect2, varscan2
- PCYT1A | c.1046C>G p.A349G | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53057583, COSV99492292; called by muse, mutect2
- PDE2A | c.1539G>A p.E513= | Splice Region (SNP) | VAF 7/28 reads (25%) | catalogued as COSV57806765; called by muse, mutect2, varscan2
- PDE8B | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as rs886060759, COSV53737698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PELI2 | c.683A>C p.Q228P | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV50711236; called by muse, mutect2, varscan2
- PES1 | c.748-1G>C p.X250_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as COSV58828550; called by muse, mutect2, varscan2
- PHETA2 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.207); catalogued as rs775937104, COSV58790891; called by muse, mutect2, varscan2
- PHLDB2 | c.3689C>T p.S1230L (on ENST00000393925 / NM_001134439.2; = p.S1187L on NM_145753.2) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56324407; called by muse, mutect2, varscan2
- PIF1 | c.930G>C p.M310I | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51421924, COSV51424397; called by muse, mutect2
- PIK3C2G | c.2046G>C p.E682D (on ENST00000676171; = p.E641D on NM_004570.5) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV56809323; called by muse, mutect2, varscan2
- PIN1 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.818); catalogued as COSV53430298; called by muse, mutect2
- PISD | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.535); catalogued as COSV60672974; called by muse, mutect2, varscan2
- PITPNC1 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV55450087; called by muse, mutect2, varscan2
- PKHD1 | c.8462A>G p.E2821G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV61875446; called by muse, mutect2, varscan2
- PLA2G2E | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV64290516; called by muse, mutect2, varscan2
- PLA2G3 | c.1515G>T p.K505N | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV53209475; called by muse, mutect2, varscan2
- PLGRKT | c.81G>A p.Q27= | Splice Region (SNP) | VAF 9/54 reads (17%) | catalogued as COSV56350240; called by muse, mutect2, varscan2
- POFUT1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756851381, COSV101003105; called by muse, mutect2, varscan2
- POU3F3 | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63721098, COSV63721745; called by muse, mutect2, varscan2
- PPEF2 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV54420156, COSV54422442; called by muse, mutect2, varscan2
- PPFIA2 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs772328431, COSV61030519; called by muse, mutect2, varscan2
- PPM1L | c.612C>G p.D204E | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV55564445; called by muse, mutect2, varscan2
- PPP1R1C | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV54715893; called by muse, mutect2
- PPP5C | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV50140215; called by muse, mutect2, varscan2
- PRAMEF1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs377131924; called by muse, mutect2, varscan2
- PRDM11 | c.487G>A p.V163M (on ENST00000530656 / NM_001359633.1; = p.V129M on NM_001256695.1) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs752009696, COSV55439971; called by muse, mutect2, varscan2
- PRDM5 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53360609; called by muse, mutect2, varscan2
- PREX2 | c.3685G>A p.V1229I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs530869739, COSV55765733; called by muse, mutect2, varscan2
- PRKN | c.992T>A p.L331* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV58226202; called by muse, mutect2, varscan2
- PRPF8 | c.4019T>G p.L1340R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV59263438; called by muse, mutect2
- PRPS1L1 | c.214A>T p.I72F | Missense Mutation (SNP) | VAF 105/449 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV72649896; called by muse, mutect2, varscan2
- PSMC3 | c.389A>C p.Q130P | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.332); catalogued as COSV54081045; called by muse, mutect2, varscan2
- PTK2B | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57756526; called by muse, mutect2, varscan2
- PTPN13 | c.5518A>G p.T1840A (on ENST00000411767 / NM_080683.3; = p.T1821A on NM_006264.3) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs1394238363, COSV57407691; called by muse, mutect2
- PTPRB | c.4322C>A p.T1441N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV54240570; called by muse, mutect2, varscan2
- PTPRB | c.1825A>T p.S609C | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.877); catalogued as COSV54240597; called by muse, varscan2
- PYCR1 | c.37T>G p.F13V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV57999258; called by muse, mutect2, varscan2
- RASGRP2 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs780100580, COSV62449480; called by muse, mutect2
- RASGRP4 | c.166T>A p.C56S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV53095461, COSV53098573; called by muse, mutect2
- RBFOX1 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.656); catalogued as rs781081302, COSV60947493; called by muse, mutect2, varscan2
- RBM4B | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV59496958; called by muse, mutect2, varscan2
- RDH11 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV67282748; called by muse, mutect2, varscan2
- RGS22 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.817); catalogued as COSV62661711; called by muse, mutect2, varscan2
- RHBDL1 | c.1034C>A p.A345D (on ENST00000219551 / NM_001318733.2; = p.A280D on NM_001278720.2) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV53483945; called by muse, mutect2, varscan2
- ROBO1 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104436313, COSV71394342; called by muse, mutect2, varscan2
- ROR1 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV64287346; called by muse, mutect2, varscan2
- RPS27A | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV55051511; called by muse, mutect2, varscan2
- RPS6KA1 | c.1559G>A p.G520D | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV65176398; called by muse, mutect2, varscan2
- RPS6KA2 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759240466, COSV55820674, COSV99692078; called by muse, mutect2, varscan2
- RRAD | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55341588; called by muse, mutect2
- RSF1 | c.1444A>C p.T482P | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV57839954; called by muse, mutect2, varscan2
- RTN3 | c.2565G>C p.K855N (on ENST00000377819 / NM_001265589.2; = p.K59N on NM_006054.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58028763; called by muse, mutect2, varscan2
- RTTN | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55344914; called by muse, mutect2, varscan2
- RYR1 | c.14340G>C p.K4780N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV62097258; called by muse, mutect2, varscan2
- RYR3 | c.9587T>C p.V3196A (on ENST00000389232; = p.V3197A on NM_001036.6) | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV101211795; called by muse, mutect2, varscan2
- RYR3 | c.9588G>A p.V3196= (on ENST00000389232; = p.V3197= on NM_001036.6) | Splice Region (SNP) | VAF 28/193 reads (15%) | catalogued as COSV101211796; called by muse, mutect2, varscan2
- SALL4 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs767807086, COSV53852210; called by muse, mutect2, varscan2
- SAMD9L | c.2042A>T p.K681I | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.742); catalogued as COSV100560188; called by muse, mutect2
- SCN1A | c.5620C>T p.R1874W (on ENST00000303395 / NM_001202435.3; = p.R1863W on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796053043, COSV57670031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51809854; called by muse, mutect2
- SCPEP1 | c.228C>T p.G76= | Splice Region (SNP) | VAF 11/130 reads (8%) | catalogued as rs201747323; called by muse, mutect2
- SCUBE3 | c.441C>G p.N147K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV51456901; called by muse, mutect2, varscan2
- SDE2 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV55251286; called by muse, mutect2, varscan2
- SERPINA10 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV56228294; called by muse, mutect2, varscan2
- SH2D3C | c.1516C>T p.R506* (on ENST00000314830 / NM_170600.3; = p.R349* on NM_005489.4) | Nonsense Mutation (SNP) | VAF 69/203 reads (34%) | catalogued as rs1156611883, COSV59120432, COSV59122863; called by muse, mutect2, varscan2
- SIGLECL1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs369324697, COSV57062874; called by muse, mutect2, varscan2
- SLC16A2 | c.1286C>G p.T429S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV52084782; called by muse, mutect2
- SLC17A2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55352005, COSV55354177; called by muse, mutect2, varscan2
- SLC17A4 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV64956210; called by muse, mutect2, varscan2
- SLC19A3 | c.907T>C p.W303R | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51452720; called by muse, mutect2, varscan2
- SLC2A4 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV50300944; called by muse, mutect2
- SLC30A10 | c.761T>A p.V254D | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100751589, COSV63071477; called by muse, mutect2, varscan2
- SLC38A6 | c.224T>G p.V75G | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV50782396; called by muse, mutect2
- SLC5A4 | c.860C>A p.A287D | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV56670421; called by muse, mutect2, varscan2
- SLC66A1 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64320894, COSV64321434; called by muse, mutect2, varscan2
- SLC6A17 | c.305A>T p.Y102F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.582); catalogued as COSV58993193; called by muse, mutect2, varscan2
- SLC7A5 | c.1518G>C p.E506D | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as COSV55364463; called by muse, mutect2, varscan2
- SLC9A2 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs780009913, COSV52128586; called by muse, mutect2
- SLCO2B1 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56935218; called by muse, mutect2, varscan2
- SLITRK6 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV68390186; called by muse, mutect2, varscan2
- SMARCA2 | c.2604C>A p.N868K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV61807450; called by muse, mutect2, varscan2
- SMPD4 | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60080222; called by muse, mutect2, varscan2
- SNX32 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV57449520; called by muse, mutect2, varscan2
- SNX32 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs137872295; called by muse, mutect2, varscan2
- SORCS3 | c.3352T>C p.S1118P | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.616); catalogued as COSV63810531; called by muse, mutect2, varscan2
- SOX6 | c.2312C>A p.P771H (on ENST00000528429 / NM_001145819.2; = p.P744H on NM_017508.3) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57045917; called by muse, mutect2, varscan2
- SPEG | c.9668T>A p.L3223Q | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56668833; called by muse, mutect2, varscan2
- SRRD | c.877A>T p.T293S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV53226177; called by muse, mutect2, varscan2
- STX2 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV55433521; called by muse, mutect2, varscan2
- STXBP5L | c.1813G>T p.D605Y | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56513684; called by muse, mutect2, varscan2
- SUPT16H | c.1794-1G>A p.X598_splice | Splice Site (SNP) | VAF 24/87 reads (28%) | catalogued as COSV53524656; called by muse, mutect2, varscan2
- SYDE2 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 116/262 reads (44%) | catalogued as rs566419733, COSV52315568; called by muse, mutect2, varscan2
- SYNE1 | c.14923G>A p.G4975R (on ENST00000367255 / NM_182961.4; = p.G4904R on NM_033071.3) | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV54981208; called by muse, mutect2, varscan2
- SYNE1 | c.7784G>T p.G2595V (on ENST00000367255 / NM_182961.4; = p.G2602V on NM_033071.3) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54981253; called by muse, mutect2, varscan2
- SYNE1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs772761179, COSV54976677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYTL5 | c.1112A>T p.Q371L | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52901045; called by muse, mutect2, varscan2
- TBC1D1 | c.3321G>C p.R1107S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV54718991; called by muse, mutect2, varscan2
- TBC1D8B | c.1525A>T p.T509S | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV52178819; called by muse, mutect2, varscan2
- TCTN3 | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 25/289 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV56447486; called by muse, mutect2
- TESPA1 | c.836C>A p.P279H (on ENST00000316577 / NM_001098815.3; = p.P141H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57258898; called by muse, mutect2, varscan2
- TEX35 | c.525T>A p.H175Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV51104927; called by muse, mutect2, varscan2
- TFPI | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV51900941; called by muse, mutect2
- TGFBI | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs766343295, COSV59351151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGFBI | c.1825A>C p.N609H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59351159; called by muse, mutect2, varscan2
- THAP10 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV51436571; called by muse, mutect2, varscan2
- THOC2 | c.523C>G p.L175V | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55545941; called by muse, mutect2, varscan2
- THSD1 | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV51628532; called by muse, mutect2
- THSD7B | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.111); catalogued as rs377577342, COSV55719261; called by muse, mutect2, varscan2
- TICAM1 | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV50232155; called by muse, mutect2, varscan2
- TMCC2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as COSV58003239; called by muse, mutect2, varscan2
- TMEM132D | c.3119C>G p.S1040* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as COSV67159241, COSV67160414; called by muse, mutect2, varscan2
- TMEM177 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV55608736; called by muse, mutect2, varscan2
- TMEM53 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV62406557, COSV62408279; called by muse, mutect2, varscan2
- TMEM98 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55582764; called by muse, mutect2, varscan2
- TNIK | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52682615; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2876G>A p.R959K | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV64100688; called by muse, mutect2, varscan2
- TPMT | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV59428872; called by muse, mutect2, varscan2
- TRIM24 | c.1676C>T p.A559V (on ENST00000343526 / NM_015905.3; = p.A525V on NM_003852.4) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs756911125, COSV58972395; called by muse, mutect2, varscan2
- TRIM40 | c.541C>G p.Q181E (on ENST00000376724; = p.Q152E on NM_138700.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.152); catalogued as COSV57156605; called by muse, mutect2
- TRIP4 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56030948; called by muse, mutect2, varscan2
- TRPC4 | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV100157792, COSV59000063; called by muse, mutect2, varscan2
- TTN | c.86657A>G p.E28886G (on ENST00000591111; = p.E21462G on NM_003319.4) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | PolyPhen probably damaging (0.997); catalogued as COSV60061719; called by muse, mutect2, varscan2
- TTN | c.17729C>T p.P5910L (on ENST00000591111; = p.P4983L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | PolyPhen probably damaging (0.999); catalogued as rs376846228, COSV59907357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBXN6 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs763463983, COSV56670902, COSV56672212; called by muse, mutect2
- UFD1 | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV54251394; called by muse, mutect2, varscan2
- UGT8 | c.1322T>A p.V441D | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV60417947; called by muse, mutect2, varscan2
- ULK1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1372824316, COSV58856766; called by muse, mutect2, varscan2
- UNC5C | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774148486, COSV71657935; called by muse, mutect2, varscan2
- UPF1 | c.2234G>C p.G745A (on ENST00000599848 / NM_001297549.2; = p.G734A on NM_002911.4) | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV53196615; called by muse, mutect2, varscan2
- USF3 | c.1652A>T p.N551I | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100325263, COSV57072686; called by muse, mutect2, varscan2
- USH2A | c.13907C>A p.P4636H | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs150600947, COSV56369297; called by muse, mutect2, varscan2
- VIT | c.2033A>C p.N678T (on ENST00000389975 / NM_001177969.1; = p.N693T on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64896683; called by muse, mutect2, varscan2
- VPS13A | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62428886; called by muse, mutect2
- VPS26C | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55706175; called by muse, mutect2, varscan2
- VPS51 | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99660762; called by muse, mutect2
- VRTN | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1187950254, COSV56441032, COSV56441514; called by muse, mutect2, varscan2
- VWA3B | c.1238G>T p.C413F | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV68243000; called by muse, mutect2, varscan2
- WDFY3 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV55700971; called by muse, mutect2
- WRAP53 | c.727T>G p.S243A | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV56833471; called by muse, mutect2
- WSB2 | c.425C>G p.T142R | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV59573981; called by muse, mutect2
- YWHAH | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as COSV50708362; called by muse, mutect2, varscan2
- ZAN | c.2323A>T p.I775F | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV61809135, COSV61811937; called by muse, mutect2, varscan2
- ZAN | c.7334G>C p.S2445T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.189); catalogued as COSV61809140; called by muse, mutect2, varscan2
- ZBED8 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 6/73 reads (8%) | catalogued as COSV68824713; called by muse, mutect2
- ZBTB16 | c.1433C>G p.T478R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as COSV60093092; called by muse, mutect2, varscan2
- ZCCHC8 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV60318257; called by muse, mutect2, varscan2
- ZMYM3 | c.2383A>T p.T795S | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58737886; called by muse, mutect2, varscan2
- ZMYND15 | c.1850G>C p.G617A (on ENST00000433935 / NM_001136046.3; = p.G578A on NM_032265.2) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52641726; called by muse, mutect2, varscan2
- ZNF200 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV67723820; called by muse, mutect2, varscan2
- ZNF404 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs765055556, COSV60987279; called by muse, mutect2, varscan2
- ZNF445 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV68538335; called by muse, mutect2, varscan2
- ZNF639 | c.1457G>C p.*486Sext*11 | Nonstop Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as rs999654312, COSV58383227; called by muse, mutect2, varscan2
- ZNF804B | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60828051; called by muse, mutect2, varscan2
- ABCA1 | c.1163_1194del p.D388Gfs*13 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel
- ABCA13 | c.11894_11898del p.L3965Sfs*35 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- ABRACL | c.38_61+1del | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | called by mutect2, pindel
- ADAMDEC1 | c.1076del p.G359Vfs*17 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel*, varscan2
- ADGRG6 | c.2664_2669+21del p.X888_splice | Splice Site (DEL) | VAF 25/99 reads (25%) | called by mutect2, pindel, varscan2
- ARHGAP29 | c.2603_2629del p.Y868_E876del | In Frame Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel
- ARID1A | c.6315_6343del p.L2106Efs*34 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | called by mutect2, pindel
- BAP1 | c.1022_1040del p.S341Tfs*15 | Frame Shift Del (DEL) | VAF 20/174 reads (11%) | called by mutect2, pindel
- BTLA | c.513_534del p.C171* | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- CCDC83 | c.213_221del p.I72_H74del | In Frame Del (DEL) | VAF 24/106 reads (23%) | called by mutect2, pindel, varscan2
- CLIP2 | c.1823_1846del p.G608_K616delinsE | In Frame Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel
- COBLL1 | c.3300del p.H1101Ifs*3 (on ENST00000392717; = p.H1063Ifs*3 on NM_014900.5) | Frame Shift Del (DEL) | VAF 15/127 reads (12%) | called by mutect2, pindel*, varscan2
- CTNND1 | c.1407_1418del p.E470_T473del | In Frame Del (DEL) | VAF 76/368 reads (21%) | called by mutect2, pindel, varscan2
- DGLUCY | c.1429+2_1429+10del p.X477_splice | Splice Site (DEL) | VAF 38/166 reads (23%) | called by mutect2, pindel, varscan2
- EXOC3L1 | c.1930_1942del p.A644Sfs*3 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- GORASP2 | c.240_274del p.E81Pfs*14 | Frame Shift Del (DEL) | VAF 50/192 reads (26%) | called by mutect2, pindel
- GRIN2C | c.524_529del p.H175_A176del | In Frame Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- IRS2 | c.4011del p.E1338Sfs*19 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel, varscan2
- ITGAM | c.793_804del p.P265_Y268del | In Frame Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- KALRN | c.8584_8596del p.D2862Sfs*4 (on ENST00000360013 / NM_001024660.4; = p.D1165Sfs*4 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- KBTBD7 | c.1957_1970del p.D653Kfs*8 | Frame Shift Del (DEL) | VAF 27/206 reads (13%) | called by mutect2, pindel
- LAD1 | c.1042_1078del p.K348Efs*19 | Frame Shift Del (DEL) | VAF 77/276 reads (28%) | called by mutect2, pindel
- LRIG3 | c.2626_2632del p.S876Afs*54 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- MACROD2 | c.992-2_994del p.X331_splice (on ENST00000642719; = p.X303_splice on NM_080676.6 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel
- MAST3 | c.1704_1733del p.V569_V578del | In Frame Del (DEL) | VAF 12/155 reads (8%) | called by mutect2, pindel
- MMP14 | c.259_269del p.A87Pfs*12 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- MYH7B | c.662_668del p.G221Vfs*58 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- OR52N5 | c.909_929del p.V304_R310del | In Frame Del (DEL) | VAF 15/113 reads (13%) | called by mutect2, pindel
- PCDHA1 | c.1781_1804del p.V594_S601del | In Frame Del (DEL) | VAF 22/130 reads (17%) | called by mutect2, pindel
- PCDHGB6 | c.2235_2260del p.E745Dfs*12 | Frame Shift Del (DEL) | VAF 40/155 reads (26%) | called by mutect2, pindel*
- PI15 | c.507_519del p.M169Ifs*12 | Frame Shift Del (DEL) | VAF 22/206 reads (11%) | called by mutect2, pindel
- RANBP2 | c.1064-13_1064del p.X355_splice | Splice Site (DEL) | VAF 36/231 reads (16%) | called by mutect2, pindel*, varscan2
- RFX5 | c.1639_1648del p.G547Ifs*16 | Frame Shift Del (DEL) | VAF 22/242 reads (9%) | called by mutect2, pindel
- SCN1A | c.1212_1213del p.L405Gfs*44 | Frame Shift Del (DEL) | VAF 31/133 reads (23%) | called by pindel, varscan2
- SPTBN4 | c.1618G>T p.V540F | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.354); called by muse, mutect2
- SYDE2 | c.2529_2535del p.K844Afs*4 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- SYNE2 | c.11632dup p.I3878Nfs*13 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- SYT10 | c.567del p.F189Lfs*21 | Frame Shift Del (DEL) | VAF 16/149 reads (11%) | called by mutect2, pindel, varscan2
- TAAR1 | c.100_131del p.I34Yfs*42 | Frame Shift Del (DEL) | VAF 23/202 reads (11%) | called by mutect2, pindel
- TG | c.6270_6297del p.D2091Qfs*53 | Frame Shift Del (DEL) | VAF 136/962 reads (14%) | called by mutect2, pindel
- TM9SF2 | c.415_434del p.L139Hfs*13 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | called by mutect2, pindel
- TRAV8-6 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- XRCC5 | c.1045_1047del p.S349del | In Frame Del (DEL) | VAF 14/84 reads (17%) | called by pindel, varscan2
- ZSCAN16 | c.549_566del p.N183_Q188del | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- ABCA12 | c.6204C>T p.G2068= (on ENST00000272895 / NM_173076.3; = p.G1750= on NM_015657.3) | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs777822338, COSV55959406; called by muse, mutect2, varscan2
- ABCC2 | c.1479G>A p.K493= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV64984378, COSV64986200; called by muse, mutect2, varscan2
- ABRA | c.795C>T p.F265= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV61732429; called by muse, mutect2, varscan2
- AC005324.2 | c.885C>A p.T295= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100371635; called by muse, mutect2
- ACIN1 | c.3111C>A p.T1037= | Silent (SNP) | VAF 59/332 reads (18%) | catalogued as COSV52976283, COSV52981893; called by muse, mutect2, varscan2
- ACSM1 | c.540C>T p.P180= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV54635847; called by muse, mutect2, varscan2
- ADAMTS18 | c.3483G>C p.L1161= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV51410125; called by muse, mutect2, varscan2
- ADCY8 | c.2436G>A p.S812= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs770621743, COSV53907613; called by muse, mutect2
- ADGRB1 | c.1233C>G p.A411= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV60096598; called by muse, mutect2, varscan2
- AL592490.1 | c.360C>T p.S120= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1301211828, COSV69426268; called by muse, mutect2, varscan2
- APOL1 | c.846C>T p.D282= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs376893988; called by muse, mutect2, varscan2
- ARMC9 | c.1158G>C p.V386= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV63020904; called by muse, mutect2, varscan2
- ATG2A | c.3321G>T p.T1107= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs765608911, COSV65966834; called by muse, mutect2, varscan2
- ATP10A | c.1245G>A p.T415= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as rs374857043, COSV63517386; called by muse, mutect2, varscan2
- ATP10D | c.2736G>A p.A912= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs201043225, COSV56707418; called by muse, mutect2, varscan2
- ATP1A2 | c.1989C>T p.H663= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs765006961, COSV63403753; called by muse, mutect2, varscan2
- ATP5F1B | c.885C>T p.D295= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV56260276; called by muse, mutect2, varscan2
- B4GALNT3 | c.942T>C p.D314= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV56752431; called by muse, mutect2
- CABYR | c.681T>C p.S227= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs770632803, COSV59110992; called by muse, mutect2, varscan2
- CDH2 | c.906G>A p.G302= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1345941740, COSV52280389, COSV52296763; called by muse, mutect2, varscan2
- CLCN3 | c.139T>C p.L47= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as COSV61627094; called by muse, mutect2, varscan2
- CNTNAP1 | c.1431G>C p.R477= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV52850568; called by muse, mutect2, varscan2
- COL22A1 | c.3729C>T p.G1243= | Silent (SNP) | VAF 138/341 reads (40%) | catalogued as rs762707737, COSV57336895; called by muse, mutect2, varscan2
- COL24A1 | c.693T>G p.S231= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV65306392; called by muse, mutect2, varscan2
- COL8A2 | c.1161A>T p.P387= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV57441767; called by muse, mutect2
- CPD | c.3351G>A p.E1117= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV56712861; called by muse, mutect2, varscan2
- CSMD3 | c.3141C>T p.P1047= (on ENST00000297405 / NM_001363185.1; = p.P943= on NM_052900.3) | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs762464951, COSV52181248, COSV99834436; called by muse, mutect2, varscan2
- DNAH17 | c.4260C>T p.T1420= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV67754370; called by muse, mutect2, varscan2
- DNAH7 | c.5424C>A p.S1808= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV56758788; called by muse, mutect2, varscan2
- DNAJB12 | c.861C>A p.I287= (on ENST00000338820; = p.I253= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV58760474; called by muse, mutect2, varscan2
- DNAJC10 | c.1965G>A p.R655= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV51138300; called by muse, mutect2, varscan2
- DNER | c.2091C>T p.I697= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs775072382, COSV59166353; called by muse, mutect2, varscan2
- EFHD1 | c.312T>C p.A104= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV51132644; called by muse, mutect2, varscan2
- EML3 | c.1407G>A p.P469= | Silent (SNP) | VAF 14/143 reads (10%) | catalogued as rs759882496, COSV53906357; called by muse, mutect2, varscan2
- EPHA8 | c.2514C>T p.P838= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV51268383; called by muse, mutect2, varscan2
- EVC2 | c.3634C>T p.L1212= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV60393930, COSV60399452; called by muse, mutect2, varscan2
- EXOC3L1 | c.1728C>T p.R576= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV52046386; called by muse, mutect2, varscan2
- EXTL3 | c.1263C>G p.R421= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV55038015; called by muse, mutect2
- FBF1 | c.852G>A p.E284= (on ENST00000586717; = p.E298= on NM_001319193.1) | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV59865074; called by muse, mutect2, varscan2
- FGF6 | c.321C>T p.S107= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs775761160, COSV57404079; called by muse, mutect2
- FLT4 | c.165C>T p.H55= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs781067773, COSV56108081; called by muse, mutect2
- FN1 | c.5217C>T p.S1739= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as rs376598003; called by muse, mutect2, varscan2
- FNDC7 | c.1200G>C p.L400= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV54753593; called by muse, mutect2, varscan2
- FOXG1 | c.1155C>T p.A385= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV57395704; called by muse, mutect2, varscan2
- FURIN | c.1746A>G p.P582= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as rs1027973968, COSV51576760; called by muse, mutect2
- FYB2 | c.357A>G p.Q119= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as rs762142310, COSV58585162; called by muse, mutect2, varscan2
- GGNBP2 | c.975G>A p.Q325= | Silent (SNP) | VAF 52/199 reads (26%) | called by muse, mutect2, varscan2
- GRHL3 | c.357A>G p.G119= (on ENST00000350501 / NM_198174.3; = p.G124= on NM_021180.3) | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as COSV52566644; called by muse, mutect2, varscan2
- GRIN2A | c.3309C>A p.R1103= | Silent (SNP) | VAF 45/226 reads (20%) | catalogued as COSV58032917; called by muse, mutect2, varscan2
- GRM1 | c.3370C>T p.L1124= | Silent (SNP) | VAF 11/138 reads (8%) | catalogued as rs769954391, COSV51147093; called by muse, mutect2
- H3C12 | c.90T>G p.A30= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV58152641; called by muse, mutect2
- HEPH | c.1518C>A p.G506= (on ENST00000343002; = p.G239= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100295612, COSV57963966; called by muse, mutect2, varscan2
- HESX1 | c.144C>T p.T48= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs1444711597, COSV55843262; called by muse, mutect2, varscan2
- HHIP | c.1860G>A p.T620= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs748140286, COSV56839683; called by muse, mutect2, varscan2
- IQSEC1 | c.1110G>A p.Q370= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs758851646, COSV56223894; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2199C>T p.S733= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV58019043, COSV58020559; called by muse, mutect2, varscan2
- KLHL1 | c.363C>T p.Y121= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV64772498; called by muse, mutect2, varscan2
- KLHL25 | c.1125G>A p.L375= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV61995106; called by muse, mutect2
- KRTAP27-1 | c.492G>A p.Q164= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as rs772601593, COSV67001217; called by muse, mutect2, varscan2
- LAMB3 | c.1842G>C p.G614= | Silent (SNP) | VAF 49/95 reads (52%) | catalogued as COSV61916883; called by muse, mutect2, varscan2
- LMNB2 | c.1395C>T p.A465= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs754958278, COSV57588059; called by muse, mutect2
- LZTS1 | c.1276C>T p.L426= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV56116865; called by muse, mutect2, varscan2
- MACF1 | c.843A>C p.P281= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV100481729; called by muse, mutect2, varscan2
- MAN2C1 | c.2811C>G p.P937= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV51228849; called by muse, mutect2, varscan2
- MED23 | c.2364C>G p.L788= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV63432489; called by muse, mutect2, varscan2
- MGAT1 | c.72G>C p.L24= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV57134051; called by mutect2, varscan2
- MKI67 | c.2301G>A p.P767= | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as rs763613616, COSV64073924; called by muse, mutect2, varscan2
- MOGAT3 | c.195G>C p.V65= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV56174434; called by muse, mutect2
- MTHFD1L | c.441C>T p.I147= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs569968062, COSV66208391; called by muse, mutect2, varscan2
- MYBPH | c.114C>T p.S38= | Silent (SNP) | VAF 25/298 reads (8%) | catalogued as COSV55138151; called by muse, mutect2
- MYH13 | c.2721A>G p.E907= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV52828785; called by muse, mutect2, varscan2
- NEK6 | c.576T>C p.G192= | Silent (SNP) | VAF 24/215 reads (11%) | catalogued as COSV57217637; called by muse, mutect2, varscan2
- NEURL1 | c.597G>A p.P199= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs774528254, COSV63913534; called by muse, mutect2, varscan2
- NLRP10 | c.490C>T p.L164= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100149462, COSV60780247; called by mutect2, varscan2
- NOTCH3 | c.768C>T p.N256= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs778247982, COSV54634789; called by muse, mutect2, varscan2
- NPC1 | c.1533G>A p.T511= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs778890495, COSV52578750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR1H2 | c.993C>T p.D331= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs781002868, COSV53800782; called by muse, mutect2, varscan2
- NXPE4 | c.234A>G p.K78= | Silent (SNP) | VAF 39/242 reads (16%) | catalogued as rs1349467466, COSV64943762; called by muse, mutect2, varscan2
- OLFML2B | c.1827C>G p.A609= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV54196451; called by muse, mutect2, varscan2
- OR4C15 | c.735T>C p.T245= (on ENST00000314644; = p.T191= on NM_001001920.2) | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV58951027; called by muse, mutect2, varscan2
- P2RX7 | c.1638G>A p.R546= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV55855187; called by muse, mutect2, varscan2
- PABPC3 | c.1407A>G p.R469= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV55800717; called by muse, mutect2, varscan2
- PASD1 | c.891C>T p.Y297= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs1193745215, COSV64855284; called by muse, mutect2, varscan2
- PRUNE2 | c.8310C>A p.P2770= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV56314187, COSV56316357; called by muse, mutect2
- PTF1A | c.72C>T p.D24= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs1445527891, COSV64735052; called by muse, mutect2, varscan2
- PTPRS | c.1464G>T p.V488= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV53619608; called by muse, mutect2, varscan2
- RFFL | c.267A>G p.Q89= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs771541570, COSV52071708; called by muse, mutect2, varscan2
- RHBG | c.63C>T p.F21= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs377604432; called by muse, mutect2, varscan2
- RIMBP2 | c.2922C>T p.V974= | Silent (SNP) | VAF 77/394 reads (20%) | catalogued as rs866605506, COSV55464017; called by muse, mutect2, varscan2
- RNF169 | c.879T>C p.C293= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV55132489; called by muse, mutect2, varscan2
- RNF40 | c.2607G>C p.L869= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV61214844; called by muse, mutect2, varscan2
- SALL1 | c.1785C>T p.S595= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs768826798, COSV51757369, COSV99179225; called by muse, mutect2, varscan2
- SCN4A | c.4269C>G p.V1423= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV71126875; called by muse, mutect2
- SEMG1 | c.1317A>T p.I439= | Silent (SNP) | VAF 17/171 reads (10%) | catalogued as COSV54872851; called by muse, mutect2, varscan2
- SF3B3 | c.1215T>C p.S405= | Silent (SNP) | VAF 41/177 reads (23%) | catalogued as COSV56787576; called by muse, mutect2, varscan2
- SLC12A3 | c.534G>A p.S178= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs140931462, COSV52638074; called by muse, mutect2, varscan2
- SLC25A15 | c.858C>G p.A286= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as COSV58557080; called by muse, mutect2, varscan2
- SLC2A3 | c.393C>T p.C131= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs1318683023, COSV50002660; called by muse, mutect2, varscan2
- SLC5A12 | c.1161A>G p.L387= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV68449037; called by muse, mutect2, varscan2
- SLC7A1 | c.348C>T p.N116= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs573863925, COSV66330547; called by muse, mutect2, varscan2
- SLC9A5 | c.1203G>C p.V401= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV55360467, COSV55362080; called by muse, mutect2, varscan2
- SLITRK5 | c.2439G>C p.L813= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100280090; called by muse, mutect2, varscan2
- SNAPC2 | c.720T>G p.L240= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV54491434; called by muse, mutect2, varscan2
- SNX6 | c.1137A>G p.T379= (on ENST00000652385; = p.T251= on NM_021249.5) | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV61918560; called by muse, mutect2, varscan2
- TAF1D | c.813T>C p.T271= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV60638098; called by muse, varscan2
- TAS2R30 | c.456T>G p.T152= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as COSV67855958; called by muse, mutect2, varscan2
- TEX14 | c.2052T>C p.D684= (on ENST00000240361 / NM_001201457.2; = p.D678= on NM_031272.5) | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV53616920; called by muse, mutect2
- TNFSF9 | c.759G>A p.S253= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV55537660; called by muse, mutect2, varscan2
- TRBV4-2 | c.66A>T p.G22= | Silent (SNP) | VAF 31/214 reads (14%) | called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1764C>T p.I588= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV61455742; called by muse, mutect2, varscan2
- TTN | c.28740A>T p.T9580= (on ENST00000591111; = p.T8653= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/232 reads (36%) | catalogued as COSV60061769; called by muse, mutect2, varscan2
- TUBB2A | c.618C>G p.A206= | Silent (SNP) | VAF 64/170 reads (38%) | catalogued as COSV61319017; called by muse, mutect2, varscan2
- UBQLN3 | c.1569C>G p.A523= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV61163286, COSV61164198; called by muse, mutect2
- UHRF1BP1 | c.1590C>T p.L530= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as rs1379162431, COSV51955500; called by muse, mutect2, varscan2
- VWC2L | c.357C>T p.H119= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs373003043; called by muse, mutect2, varscan2
- ZBTB46 | c.1458C>T p.A486= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs773333338, COSV55510096; called by muse, mutect2, varscan2
- ZFHX3 | c.1389G>A p.A463= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs376777497; called by muse, mutect2, varscan2
- ZIM2 | c.1149T>G p.T383= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV55633455; called by muse, mutect2, varscan2
- ZNF213 | c.1098G>A p.V366= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV67727743; called by muse, mutect2, varscan2
- ZNF341 | c.1002C>T p.N334= (on ENST00000375200 / NM_001282935.1; = p.N327= on NM_032819.4) | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs1399222668, COSV61008495; called by muse, mutect2, varscan2
- ZNF648 | c.1044G>A p.S348= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs866822851, COSV100374560, COSV60570923; called by muse, mutect2
- C17orf58 | c.103+107A>T | Intron (SNP) | VAF 22/106 reads (21%) | catalogued as COSV100558696; called by muse, mutect2, varscan2
- CABP1 | c.655-9237_655-9216del | Intron (DEL) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
- CCDC140 | n.638T>A | RNA (SNP) | VAF 14/40 reads (35%) | catalogued as COSV54675650; called by muse, mutect2, varscan2
- CIT | c.4729-446C>G | Intron (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- CSF3 | c.*1G>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99842208; called by muse, mutect2, varscan2
- DCHS2 | n.3739C>T | RNA (SNP) | VAF 5/64 reads (8%) | catalogued as COSV61772046; called by muse, mutect2
- DCHS2 | n.3392A>T | RNA (SNP) | VAF 94/298 reads (32%) | catalogued as COSV59726489; called by muse, mutect2, varscan2
- GH2 | c.456+51G>C | Intron (SNP) | VAF 41/172 reads (24%) | catalogued as COSV100236758, COSV60427361; called by muse, mutect2, varscan2
- GRIA4 | c.2295-5892C>T | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs771428091, COSV99228029; called by mutect2, varscan2
- HLA-F | c.1036+169T>C | Intron (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- MFRP | chr11:119346372 G>A | 5'Flank (SNP) | VAF 12/57 reads (21%) | catalogued as rs368205663; called by muse, mutect2, varscan2
- MIR376A2 | n.26C>G | RNA (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- MIR551B | n.55G>A | RNA (SNP) | VAF 7/146 reads (5%) | catalogued as rs999872124; called by muse, mutect2
- P2RY6 | c.*6_*23del | 3'UTR (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- PAX7 | c.1402+49C>A | Intron (SNP) | VAF 7/40 reads (18%) | catalogued as rs142059630, COSV64750179; called by muse, mutect2, varscan2
